Surgical pathology report (de-identified scan), TCGA case TCGA-3S-AAYX, project TCGA-THYM (Thymoma), tissue source site University of New Mexico, specimen TCGA-3S-AAYX-01A (Primary Tumor).

[page 1 of 3]
Result type: Surgical Pathology Final Report
Result date:
Result status: Auth (Verified)
Result title: Surgical Procedure
Performed by: [REDACTED]
Verified by: [REDACTED]
Encounter info: [REDACTED]
Contributor system: [REDACTED]

ICD-O-3
Thymoma, type B1
malignant 8583/1
Site: Thymus C37.9
QJ 3/11/14

*** Final Report ***

Surgical Procedure

CASE: [REDACTED]
PATIENT: [REDACTED]

SPECIMENS SUBMITTED:

A. EXTENDED THYMECTOMY

DIAGNOSIS:

A. MEDIASTINUM, THYMUS; THYMECTOMY:

- THYMOMA, TYPE B1 (PREDOMINANTLY CORTICAL)
- TUMOR SIZE: 5.8 cm.
- TUMOR INVASION.
- TUMOR CAPSULE/MEDIASTINAL FAT: INVASION INTO SURROUNDING FAT

PRESENT.

- PLEURA/PERICARDIUM: NOT PRESENT FOR EVALUATION.
- LUNG PARENCHYMA: NOT PRESENT FOR EVALUATION.
- DIAPHRAGM: NOT PRESENT FOR EVALUATION.
- LYMPH VASCULAR INVASION: NEGATIVE.
- IMPLANT/DISTANT METASTASES: NOT PRESENT FOR EVALUATION.
- SPECIMEN CHARACTERISTICS.
- SPECIMEN WEIGHT: 175 GRAMS.
- SPECIMEN INTEGRITY: INTACT.
- MARGINS: TUMOR PRESENT AT INKED SUPERFICIAL MARGIN AND WITHIN 2 mm OF THE INKED POSTERIOR/DEEP MARGIN.
- TREATMENT EFFECT: NOT APPLICABLE.

[page 2 of 3]
- REGIONAL LYMPH NODES: 9 LYMPH NODES IDENTIFIED NEGATIVE FOR METASTASIS.

- OTHER FINDINGS: SEGMENT OF BENIGN PARATHYROID TISSUE IDENTIFIED.

- PATHOLOGIC STAGE: WITHIN . : STAGE II

CLINICAL INFORMATION: [REDACTED].

GROSS DESCRIPTION: Number of specimen containers: 1. Labeled with patient name [REDACTED] and MRN [REDACTED].

A. Container designation: "extended thymectomy" -- Received unfixed is a thymectomy specimen weighing 175 grams, measuring 32.5 x 10.5 x 3.0 cm in overall dimension. A suture identifies the right superficial and superior margin. The entire superficial margin is inked yellow, the posterior is inked green. Sectioning through the fat demonstrates a well-circumscribed gray glistening, fleshy mass and friable, 5.8 x 5.3 x 3.0 cm which grossly abuts the anterior and posterior soft tissue margins. Representative sections (under sterile technique) are submitted for cytogenetics. Additional sections are submitted in [REDACTED] for flow cytometry. Touch preps are performed. Representative sections of tumor and normal are submitted to [REDACTED]. Sectioning of the remaining tissue demonstrates yellow glistening cut surfaces. No other lesions are grossly identified. The specimen is submitted for photographic documentation. Sections are submitted as follows: A1 - tumor abutting superficial margin; A2 - tumor abutting posterior/deep margin; A3-A4 - representative sections of tumor submitted in AZF fixative and re-submitted for permanent; A5 - additional sections of tumor; A6-A8 - presumed lymph nodes in their entirety.

(Dictated by: [REDACTED]) ([REDACTED])

MICROSCOPIC DESCRIPTION: Histologic examination performed.

IMMUNOHISTOCHEMICAL STUDY:

Cytokeratin is performed and reveals abundance of scattered epithelial cells.

[page 3 of 3]
Any tests performed using Analytic Specific Reagents (ASR) were developed and validated by [REDACTED]. The U.S. Food and Drug Administration has not approved these tests but has determined that such clearance or approval is not necessary. These tests should be regarded as a clinical assay for standard medical care.

The [REDACTED] was present during the formal review and interpretation of all slides and ancillary studies, (if performed), with the [REDACTED]. Specimens with only gross examination were reviewed and interpreted by the [REDACTED].

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 3c5cfd5c-a37e-4fc0-a4e6-0ca727cb624c (TCGA-3S-AAYX.6C131213-2F94-4A92-B62D-D8D40A77C9FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).